Surgical pathology report (de-identified scan), TCGA case TCGA-KN-8418, project TCGA-KICH (Kidney Chromophobe), tissue source site Harvard, specimen TCGA-KN-8418-01A (Primary Tumor).

[page 1 of 5]
Surgical Pathology Report

Specimen: [REDACTED] RTB MARROW SQUEEZE

SPECIMEN LABELED "10TH RIB":

Bone marrow with maturing trilineage hematopoiesis.
There is no evidence of malignancy.

SPECIMEN LABELED "RIGHT KIDNEY" (INCLUDING FSA1 AND FSA2):

RENAL CELL CARCINOMA (10.0 cm), chromophobe type, Fuhrman nuclear grade III/IV.

Lymphovascular invasion is identified, by the renal vein of tumor.

Tumor does not invade the renal capsule.

Surgical soft tissue resection margins are free of tumor.

Ureter, renal artery, and renal vein margins are free of tumor.

Non lesional kidney with no significant pathologic change.

The adrenal gland is not present.

Utilities Help Goodbye

Surgical Pathology Report

Specimen: [REDACTED] RTB MARROW SQUEEZE

Hale's colloidal iron stain is positive in tumor cells, supporting the diagnosis of chromophobe type.

SPECIMEN LABELED "REGIONAL LYMPH NODES":

Three lymph nodes negative for tumor.

AJCC classification: T2 N0 Mx

SURGICAL ADDENDUM:

The diagnosis for part 2 contains a typographical error; the relevant part

[page 2 of 5]
Surgical Pathology Report

Specimen

RIB MARROW SQU

should read "Lymphovascular invasion is identified, but the renal vein is free of tumor."

The remaining diagnoses are unchanged.

CLINICAL DATA:

History: None given.

Operation: R radical nephrectomy.

Clinical Diagnosis: R renal mass.

ISSUE SUBMITTED: 1. 10th rib.

2. Right kidney.

3. Regional lymph nodes.

O.R. CONSULTATION REPORT:

Surgical Pathology Report

SPECIMEN LABELED "RIGHT KIDNEY" (FSA1, FSA2):

9.6 cm mass consistent with renal cell carcinoma.

Consistent with renal cell carcinoma (see note).

NOTE: The pattern is slightly unusual but favors RENAL CELL CARCINOMA over TRANSITIONAL CELL CARCINOMA. (It may be a chromophobe RENAL CELL CARCINOMA.)

GROSS DESCRIPTION:

The specimen is received in three parts, received fresh, labeled with the patient's name and unit number.

Specimen #1 is "10th rib" and consists of a single rib (6.5 x 1.5 x 0.6 cm).

Micro 1: rib marrow squeeze, multi frags.

[page 3 of 5]
Surgical Pathology Report

Specimen #2 is "right kidney" and consists of a radical nephrectomy specimen (16 x 8 x 7.5 cm, 447 grams) that contains a tan, lobulated, focally hemorrhagic mass, (10.0 x 7.0 cm) at the lower pole that pushes out on the capsule but does not appear to penetrate the capsule. The renal pelvis and ureter, and the renal vein are grossly free of tumor. The renal cortex and medulla away from the tumor are grossly unremarkable. No adrenal gland is identified in the perinephric fat. Representative samples of solid areas x3 are submitted as FSA1. The cystic areas x2 are submitted as FSA2. Representative sections of solid and cystic areas, normal cortex and medulla are taken for tumor bank.

Micro 2: Frozen section remnant, FSA1, 2 frags, ESS.
Micro 3: frozen section remnant, FSA2, 2 frags, ESS.
Micro 4: ureter, artery and veins, 3 frags, RSS.
Micro 5-9: tumor, 1 frag each, RSS.

Surgical Pathology Report

Micro 10: adjacent uninvolved kidney, 1 frag, RSS.
Micro 11: tumor adjacent to renal pelvis, 2 frags, RSS.

Specimen #3 is "regional lymph nodes" and is a single fragment of pink/gray soft tissue (2.3 x 1.1 x 1.0 cm). Three lymph nodes are identified.

Micro 12: 2 lymph nodes, 1 frag, ESS.
Micro 13: largest lymph node (1.5 cm), bisected, 2 frags, ESS.
mk

---- End of Text ----

[page 4 of 5]
Utilities Help Goodbye

Specimen [REDACTED] Surgical Pathology Report
[REDACTED] MORROW SQUFFZI

Specimen #2 is "right kidney" and consists of a radical nephrectomy specimen (16 x 8 x 7.5 cm, 447 grams) that contains a tan, lobulated, focally hemorrhagic mass. (10.0 x 7.0 cm) at the lower pole that pushes out on the capsule but does not appear to penetrate the capsule. The renal pelvis and ureter, and the renal vein are grossly free of tumor. The renal cortex and medulla away from the tumor are grossly unremarkable. No adrenal gland is identified in the perinephric fat. Representative samples of solid areas x3 or submitted as FSA1. The cystic areas x2 are submitted as FSA2. Representative sections of solid and cystic areas, normal cortex and medulla are taken for tumor bank.

Micro 2: frozen section remnant, FSA1, 2 frags, ESS.
Micro 3: frozen section remnant, FSA2, 2 frags, ESS.
Micro 4: ureter, artery and veins, 3 frags, RSS.
Micro 5-9: tumor, 1 frag each, RSS.

Utilities Help Goodbye

[REDACTED]

Micro 10: adjacent uninvolved kidney, 1 frag, RSS.
Micro 11: tumor adjacent to renal pelvis, 2 frags, RSS.

Specimen #3 is "regional lymph nodes" and is a single fragment of pink/gray soft tissue (2.3 x 1.1 x 1.0 cm). Three lymph nodes are identified.

Micro 12: 2 lymph nodes, 1 frag, LSS.
Micro 13: largest lymph node (1.5 cm), bisected, 2 frags, ESS.
mrk

----- End of Text -----

[page 5 of 5]
PICS Terminal [Utilities] [Help] [Goodbye] [Dim] [X]

Utilities Help Goodbye

Surgical Pathology Report

[REDACTED]

should read "Lymphovascular invasion is identified, but the renal vein is free of tumor."

The remaining diagnoses are unchanged.

CLINICAL DATA:
History: None given.
Operation: R radical nephrectomy.
Clinical Diagnosis: R renal mass.

TISSUE SUBMITTED: 1. 10th rib.
2. Right kidney.
3. Regional lymph nodes.

O.R. CONSULTATION REPORT:

PICS Terminal [Utilities] [Help] [Goodbye] [Dim] [X]

Utilities Help Goodbye

Surgical Pathology Report

[REDACTED]

SPECIMEN LABELED "RIGHT KIDNEY" (FS01, FS02):
9.6 cm mass consistent with renal cell carcinoma.
Consistent with renal cell carcinoma (see note).

NOTE: The pattern is slightly unusual but favors RENAL CELL CARCINOMA over TRANSITIONAL CELL CARCINOMA. (It may be a chromophobe RENAL CELL CARCINOMA.)

GROSS DESCRIPTION: [REDACTED] [REDACTED]
The specimen is received in three parts, received fresh, labeled with the patient's name and unit number.

Specimen #1 is "10th rib" and consists of a single rib (6.5 x 1.5 x 0.6 cm).

Micro 1: rib marrow squeeze, multi frags, RSS.

Source: NCI Genomic Data Commons file 8f979415-c094-42ea-9797-f199d8ec6792 (TCGA-KN-8418.5CF28DE7-02EB-4CF2-82CF-6B0F6F0B6FD4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).